Gene-level copy-number profile of tumor specimen ALCH-AEL8-TTP1-A from ALCHEMIST case ALCH-AEL8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.2 years (21,990 days).
Specimen ALCH-AEL8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d3710a24-5b43-41dc-bd5a-b4ecadd84134.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEL8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/64d98d63-cdcf-4fcc-b31e-29f7715fa76d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 15,141; copy number 2: 41,150; copy number 3: 2,019; copy number 4: 82; copy number 5: 2; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,699,456–143,699,619, 1 gene: RNVU1-17.
- chr3:52,777,595–52,809,009, 2 genes: ITIH1, ITIH3.
- chr4:3,758,748–3,768,526, 2 genes: LINC02600, ADRA2C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:990,509–1,495,933, 2 genes, copy number 5 (within-gene range 3–5): ERC1, HTR1DP1.
- chr22:20,338,805–20,354,387, 3 genes, copy number 6 (within-gene range 2–6): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 12,798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
